Surgical pathology report (de-identified scan), TCGA case TCGA-B6-A0IM, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Duke, specimen TCGA-B6-A0IM-01A (Primary Tumor).

[page 1 of 2]
100-0-3

Carcinoma, ductal, infiltrating 8500/3

Patient:

Path Site Code: breast, upper outer quadrant C50.4 11/7/11
CQCF: breast, NIS C50.9**Surgical Pathology****Surg Path**UUID: 4A86A028-C56D-455E-A5CD-47D8A34B5734

CLINICAL HISTORY:
Not provided.**GROSS EXAMINATION:**

A. "Right breast mass #1", received fresh labeled with the patient's name and record number for frozen section is a 4 x 2.9 x 2.2 cm specimen with a 2 x 2 x 1.3 cm tumor. The frozen section remnant is submitted in A1. A2-A4 represent full cross sections of the tumor and adjacent tissue.

B. "Right breast, long lateral short superior", received fresh is a right mastectomy specimen weighing 2040 grams. The skin ellipse measures 34.5 x 17.5 cm, has a 4 cm areola and a 0.9 cm nipple. A suture marks the lateral aspect of the specimen. The breast measures 35 x 23 x 6 cm with an 8 x 6.5 x 1 cm axillary tail. In the upper outer quadrant is a recent sutured surgical incision 7 cm. The soft tissue margins are inked blue. Sectioning shows a recent biopsy cavity approximately 5 cm in diameter deep to the suture. On the medial aspect of this biopsy cavity, another tumor is identified. While contiguous with the cavity, the bulk of the tumor is more medial. This is felt to represent a single "dumbbell" shaped tumor rather than two separate tumors. Maximal dimensions of this tumor are 5 x 3.5 x 3 cm. This tumor is also located in the upper lateral quadrant and is 2 cm from the deep resection margin. Further firm tissue suspicious for tumor is identified in the lateral aspect of the biopsy cavity and measures 2 cm. Again this is 2 cm from the deep resection margin. Measuring from the medially located tumor to the lesion present at the lateral aspect of the biopsy cavity the maximum tumor diameter is 7 cm. The axilla is sampled from medial to lateral.

BLOCK SUMMARY:

- B1 - lateral aspect of biopsy cavity.
- B2 - medial aspect of the biopsy cavity.
- B3&B4 - tumor in upper outer quadrant
- B5 - tissue from lower lateral quadrant.
- B6 - tissue, upper inner quadrant.
- B7 - tissue, lower inner quadrant.
- B8&B9 - nipple
- B10&B11 - deep margin
- B12 - one lymph node, serially sectioned.
- B13 - two lymph nodes, one inked red.
- B14 - three node candidates.
- B15 - one lymph node
- B16 - highest node (near suture)

INTRA OPERATIVE CONSULTATION:

- A. "Right breast mass (AF1)" - infiltrating ductal carcinoma present. (Dr.

****REVISED DIAGNOSIS**:**

This report is being revised to correct the specimen "B" site from "left" to "right" breast. The remainder of the diagnosis is unchanged.

- A. "RIGHT BREAST MASS", (INCISIONAL BIOPSY):

INFILTRATE DUCTAL CARCINOMA WITH PROMINENT CRIBRIFORM PATTERN.
TUMOR SIZE; 2 CM.

- B. "RIGHT BREAST", (MASTECTOMY):

[page 2 of 2]
INFILTRATING CARCINOMA, PRESENT. HISTOLOGIC TYPE, DUCTAL WITH A PROMINENT CRIBRIFORM COMPONENT.

N.S.A.B.P. HISTOLOGIC GRADE 1 OF 3.

N.S.A.B.P. NUCLEAR GRADE 2 OF 3.

GROSS TUMOR SIZE; 7 CM. SEE COMMENT.

INVASION TUMOR SIZE, 7 CM. SEE COMMENT.

LOCATION, UPPER OUTER QUADRANT.

MULTIFOCAL TUMOR, NO.

IN-SITU CARCINOMA, ABSENT.

STATUS OF NON-NEOPLASTIC BREAST TISSUE; SCLEROSING ADENOSIS WITH MICROCALCIFICATIONS.

LYMPHATIC/VASCULAR INVASION ABSENT.

SURGICAL MARGIN STATUS, NEGATIVE.

NIPPLE STATUS; PAGET'S DISEASE ABSENT.

SKIN STATUS; FREE OF TUMOR.

MUSCLE STATUS; NOT SAMPLED.

LYMPH NODES STATUS; 9 LYMPH NODES, NO CARCINOMA IDENTIFIED (0/9).

ESTROGEN/PROGESTERONE AND CELL CYCLE ANALYSIS PENDING, YES.

METHODOLOGY, FRESH TISSUE.

RESULTS WILL BE ISSUED IN AN ADDENDUM.

COMMENT: The tumor size in the mastectomy specimen is 7 cm in greatest dimension and the size of the tumor in the incisional biopsy is 2 cm. The overall tumor size is mostly likely 9 cm in greatest dimension. The results of this revision has been discussed with= on

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

~~Date~~

ADDENDUM 1:

Tissue was sent to the _____ for assay of the estrogen and progesterone receptors. The estrogen receptor activity was judged to be positive with an estimated FMOL value of 113. The progesterone receptor activity was judged as borderline with an estimated FMOL of value of 14. Please refer to _____ for a complete report.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

~~Date~~

Source: NCI Genomic Data Commons file 17b23940-3aeb-4179-baac-43bb5d413b36 (TCGA-B6-A0IM.4A86A028-C56D-455E-A5CD-47D8A34B5734.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).